Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3QD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3QD-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 2.6 x 2.5 x 0.98 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: 1/6 positive for metastasis (Pelvic 1/6)

Lymphatic invasion: Present

Venous invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

squamous cell carcinoma, NOS
8070/3

Site: cervix, NOS C53.9 2-28-12 RD

2/21/12

Source: NCI Genomic Data Commons file f0a1041f-df4d-43c1-a84c-f528f6e91994 (TCGA-EA-A3QD.C5F8BF41-F7A7-4870-890E-861D2DE51DBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).